Somatic mutation profile of tumor specimen 0DZY59 from CCDI case PBCUJM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DZY59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1aec4976-5ea8-4ea0-aab0-84deca14c0ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZY6B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6526d96-33e2-417e-ba92-21b1946da0c6

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCTD4 | c.542A>C p.D181A | Missense Mutation (SNP) | VAF 50/1224 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61239642; called by muse, mutect2
- DUSP6 | c.838+1dup p.X280_splice | Splice Site (INS) | VAF 120/294 reads (41%) | called by mutect2, varscan2
- NHSL1 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 57/568 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 18/602 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- NLRP4 | c.669G>A p.P223= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as rs746075034, COSV56707602, COSV56708334; called by muse, mutect2, varscan2
- PASD1 | c.198A>T p.G66= | Silent (SNP) | VAF 83/1610 reads (5%) | catalogued as rs745789465; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 44/1756 reads (3%) | called by muse, mutect2
- ESX1 | c.*80G>A | 3'UTR (SNP) | VAF 4/55 reads (7%) | catalogued as rs1556393550; called by muse, mutect2
- LRP11 | c.*32_*33del | 3'UTR (DEL) | VAF 30/256 reads (12%) | called by mutect2, varscan2
